Somatic mutation profile of tumor specimen TCGA-XV-A9W2-01A (aliquot TCGA-XV-A9W2-01A-11D-A397-08) from TCGA case TCGA-XV-A9W2, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 81.7 years (29,836 days).
Specimen TCGA-XV-A9W2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8c96996-d15d-4136-a193-c227a3fe0ed2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XV-A9W2-10A (Blood Derived Normal), aliquot TCGA-XV-A9W2-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f85d4b34-10e4-4450-b6eb-2de01cfcbb74

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 26, Silent 13, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 11/53 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67230348; called by muse, mutect2
- ALPK2 | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as COSV100864789; called by muse, mutect2, varscan2
- AMBP | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV99469355; called by muse, mutect2, varscan2
- ARC | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs776707820, COSV100751656; called by muse, mutect2, varscan2
- CDH7 | c.324G>C p.K108N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100543189; called by muse, mutect2, varscan2
- CYP4Z1 | c.1129G>A p.A377T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs999250046, COSV100497915; called by muse, mutect2, varscan2
- DENND4C | c.3644A>T p.N1215I (on ENST00000434457 / NM_001330640.2; = p.N1166I on NM_017925.7) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as COSV100727597; called by muse, mutect2, varscan2
- DOP1A | c.4778A>G p.E1593G | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99382869; called by muse, mutect2, varscan2
- GYPC | c.194T>G p.V65G | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV52148161, COSV99392065; called by muse, mutect2, varscan2
- HBM | c.353C>G p.T118S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV100720802; called by muse, mutect2, varscan2
- HSF2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs144007130; called by muse, mutect2, varscan2
- LRP1B | c.10522G>C p.E3508Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.268); catalogued as COSV101256794, COSV101260608, COSV67239114; called by muse, mutect2, varscan2
- MDN1 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs902874230, COSV101021812; called by muse, mutect2
- MYOF | c.976G>A p.G326R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs955402113, COSV63706195; called by muse, mutect2, varscan2
- NF1 | c.6427+1G>C p.X2143_splice (on ENST00000358273 / NM_001042492.3; = p.X2122_splice on NM_000267.3) | Splice Site (SNP) | VAF 31/63 reads (49%) | catalogued as CD1413935, CS087444, COSV100648209, COSV62199155; called by muse, mutect2, varscan2
- NPAS2 | c.901C>A p.Q301K | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs1428761736, COSV100176919; called by muse, mutect2, varscan2
- OR51B6 | c.696G>T p.R232S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as COSV100972032, COSV66512869; called by muse, mutect2, varscan2
- P2RX6 | c.1104C>G p.F368L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs1267985524, COSV100298866; called by muse, mutect2
- PCDHA6 | c.1708G>C p.V570L | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV100971784; called by muse, mutect2, varscan2
- PRPF4B | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100528379; called by muse, mutect2, varscan2
- RBBP6 | c.1798C>A p.P600T | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV100154939, COSV60504576; called by muse, mutect2, varscan2
- RTEL1 | c.3148C>G p.P1050A | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV99423312; called by muse, varscan2
- TCIM | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.3); PolyPhen possibly damaging (0.845); catalogued as COSV100249675; called by muse, mutect2, varscan2
- TEX45 | c.682-1G>A p.X228_splice | Splice Site (SNP) | VAF 15/50 reads (30%) | catalogued as rs1437436395, COSV100861828; called by muse, mutect2, varscan2
- TFPT | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as COSV100320123; called by muse, varscan2
- TNK1 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV100294982; called by muse, varscan2
- TPCN2 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | catalogued as COSV99593938; called by muse, mutect2, varscan2
- TUB | c.223C>T p.L75F (on ENST00000299506 / NM_177972.3; = p.L130F on NM_003320.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as rs865852581, COSV100210437; called by muse, mutect2, varscan2
- ZNF460 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100828125; called by muse, mutect2, varscan2
- TP73 | c.1490dup p.L497Ffs*30 | Frame Shift Ins (INS) | VAF 19/75 reads (25%) | called by mutect2, pindel, varscan2
- CLVS1 | c.381C>A p.P127= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs763611025, COSV100370651; called by muse, mutect2, varscan2
- DTWD1 | c.60G>A p.V20= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as rs1411391159, COSV99233780; called by muse, mutect2
- ETFB | c.708C>T p.G236= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs749837573, COSV58537369; called by muse, mutect2, varscan2
- HHIPL1 | c.873C>T p.D291= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs761419695, COSV100415376; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.249C>T p.F83= | Silent (SNP) | VAF 35/170 reads (21%) | called by muse, mutect2, varscan2
- KDM6B | c.3381G>A p.R1127= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs1254482218, COSV99642242; called by muse, mutect2
- NSMCE2 | c.552G>A p.V184= | Silent (SNP) | VAF 24/95 reads (25%) | catalogued as COSV99787376; called by muse, mutect2, varscan2
- SCN3A | c.294A>G p.A98= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV99328446; called by muse, mutect2, varscan2
- TENM3 | c.1734G>C p.P578= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV101305457; called by muse, mutect2, varscan2
- TFIP11 | c.981C>T p.L327= | Silent (SNP) | VAF 72/135 reads (53%) | catalogued as rs377039376; called by muse, mutect2, varscan2
- TFPT | c.333G>C p.R111= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100338299; called by muse, mutect2
- TFPT | c.123G>A p.L41= | Silent (SNP) | VAF 51/186 reads (27%) | catalogued as COSV100320122; called by muse, mutect2, varscan2
- TOR1A | c.312A>T p.T104= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as COSV100693986; called by muse, mutect2, varscan2
